Somatic mutation profile of tumor specimen MP2PRT-PARJZZ-TMP1-A (aliquot MP2PRT-PARJZZ-TMP1-A-1-0-D-A82A-36) from MP2PRT case MP2PRT-PARJZZ, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.2 years (1,538 days).
Specimen MP2PRT-PARJZZ-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4fb07077-fce6-48fa-95cd-44dbdad97052.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARJZZ-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARJZZ-NB1-A-1-0-D-A82A-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ac926c44-39c0-43b9-bfd3-8e1a63e24265

The open-access MAF lists 17 somatic variants for this specimen: 13 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 9, Silent 4, Frame Shift Ins 2, Frame Shift Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 79/389 reads (20%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- CNTN6 | c.2257del p.V753Cfs*37 | Frame Shift Del (DEL) | VAF 90/238 reads (38%) | catalogued as COSV63192743; called by mutect2, pindel*, varscan2
- HSH2D | c.608T>G p.L203R | Missense Mutation (SNP) | VAF 211/483 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV53738820; called by muse, mutect2, varscan2
- KMT2D | c.6656_6657insAGTACGTTAGTA p.G2219_A2220insVR* | Nonsense Mutation (INS) | VAF 218/804 reads (27%) | catalogued as COSV56493533; called by pindel, varscan2
- NUMBL | c.1063G>A p.G355S | Missense Mutation (SNP) | VAF 109/420 reads (26%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as rs138049709; called by muse, mutect2, varscan2
- POLRMT | c.3352G>A p.G1118S | Missense Mutation (SNP) | VAF 170/458 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); catalogued as rs143273183; called by muse, mutect2, varscan2
- QPRT | c.481C>T p.R161C | Missense Mutation (SNP) | VAF 212/539 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs767025196, COSV54880156; called by muse, mutect2, varscan2
- SUN2 | c.148A>T p.M50L | Missense Mutation (SNP) | VAF 92/365 reads (25%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV53305516; called by muse, mutect2, varscan2
- TFF3 | c.170G>A p.G57D | Missense Mutation (SNP) | VAF 110/525 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52295226; called by muse, mutect2, varscan2
- USH2A | c.3763A>C p.S1255R | Missense Mutation (SNP) | VAF 101/291 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as COSV56450474; called by muse, mutect2, varscan2
- ZNF716 | c.341G>T p.R114I | Missense Mutation (SNP) | VAF 27/161 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.009); catalogued as rs782102491, COSV70780784; called by muse, mutect2, varscan2
- CA5A | c.690_691insCCCC p.A231Pfs*24 | Frame Shift Ins (INS) | VAF 163/557 reads (29%) | called by mutect2, pindel, varscan2
- LOXL2 | c.1901_1902insCCCCCTCCCTAGGGGGT p.F635Pfs*13 | Frame Shift Ins (INS) | VAF 113/384 reads (29%) | called by mutect2, pindel, varscan2
- MAGI1 | c.2853C>A p.I951= (on ENST00000402939 / NM_001033057.2; = p.I979= on NM_004742.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 146/730 reads (20%) | called by muse, mutect2, varscan2
- MLLT1 | c.639C>T p.S213= | Silent (SNP) | VAF 146/658 reads (22%) | catalogued as COSV53133756; called by muse, mutect2, varscan2
- ZNF503 | c.1248G>A p.A416= | Silent (SNP) | VAF 183/820 reads (22%) | catalogued as rs763125350; called by muse, mutect2, varscan2
- ZNF618 | c.2373G>A p.A791= (on ENST00000374126 / NM_001318042.2; = p.A698= on NM_133374.2) | Silent (SNP) | VAF 248/560 reads (44%) | catalogued as rs147007253, COSV55931344; called by muse, mutect2, varscan2
